Somatic mutation profile of tumor specimen TCGA-IM-A4EB-01A (aliquot TCGA-IM-A4EB-01A-11D-A257-08) from TCGA case TCGA-IM-A4EB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nonencapsulated sclerosing carcinoma; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.3 years (13,635 days).
Specimen TCGA-IM-A4EB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f3943ae-1f4a-4d8c-ad92-97c9991e1b77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IM-A4EB-10A (Blood Derived Normal), aliquot TCGA-IM-A4EB-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a8ee368-2694-4d88-bc09-67c632b7e2e6

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANXA7 | c.1287G>T p.M429I (on ENST00000372919 / NM_001320880.2; = p.M407I on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100873380; called by muse, mutect2, varscan2
- AP2B1 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 15/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99250726; called by muse, mutect2
- DVL2 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.127); catalogued as rs1170581733, COSV99138261; called by muse, mutect2, varscan2
- GBA2 | c.2711A>G p.K904R | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV100147188; called by muse, mutect2, varscan2
- INF2 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.105); catalogued as rs777010216, COSV53029479, COSV99383384; called by muse, mutect2, varscan2
- ITGB2 | c.1610T>C p.V537A (on ENST00000302347; = p.V513A on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV100185507; called by muse, mutect2, varscan2
- RAB3IP | c.808G>T p.E270* (on ENST00000550536 / NM_175623.4; = p.E254* on NM_022456.5) | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99922872; called by muse, mutect2, varscan2
- RPL13A | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs569616137, COSV99201261; called by muse, mutect2, varscan2
- SAMD3 | c.440A>T p.Y147F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV100148090; called by muse, mutect2, varscan2
- FAM3C | c.186del p.A63Lfs*30 | Frame Shift Del (DEL) | VAF 11/112 reads (10%) | called by pindel, varscan2*
- ADAMTS2 | c.2529C>T p.V843= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs754467396, COSV52375862; called by muse, mutect2, varscan2
- PRAMEF10 | c.954C>T p.S318= | Silent (SNP) | VAF 31/525 reads (6%) | catalogued as rs1361003466; called by muse, mutect2
